Somatic mutation profile of tumor specimen TCGA-H7-A76A-01A (aliquot TCGA-H7-A76A-01A-51D-A34J-08) from TCGA case TCGA-H7-A76A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 57.3 years (20,946 days).
Specimen TCGA-H7-A76A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f97d844-efa5-4530-991d-61952a2b46cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H7-A76A-10A (Blood Derived Normal), aliquot TCGA-H7-A76A-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31ff30ef-a365-45b3-b505-66bc3c86f8fb

The open-access MAF lists 76 somatic variants for this specimen: 52 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 23, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367634557, CM1515479; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs372858576; called by muse, mutect2
- ADAMTSL1 | c.2078G>A p.C693Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191593296, COSV101002037; called by muse, mutect2, varscan2
- ADGRL1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.553); catalogued as COSV100529781; called by muse, mutect2, varscan2
- ALMS1 | c.6775C>G p.L2259V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748833907, COSV100043466; called by muse, mutect2, varscan2
- ANGPTL8 | c.119A>T p.H40L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV99371091; called by muse, varscan2
- ASPA | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.962); catalogued as COSV99559309; called by muse, mutect2, varscan2
- ATP8A2 | c.2962G>C p.V988L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99683903; called by muse, mutect2, varscan2
- C3orf18 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113250784, COSV51750106; called by muse, mutect2, varscan2
- CCR3 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV100656741; called by muse, mutect2, varscan2
- CDH18 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV56947923; called by muse, mutect2, varscan2
- CEP55 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV101017133; called by muse, mutect2, varscan2
- CLK4 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV100309080; called by muse, mutect2, varscan2
- DHX37 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139345740; called by mutect2, varscan2
- DMRTA1 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100364876; called by muse, mutect2, varscan2
- EML2 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.391); catalogued as COSV99840396; called by muse, mutect2
- FBXL6 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs201941787; called by muse, mutect2, varscan2
- FGF12 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1305557640, COSV53169187; called by muse, mutect2, varscan2
- FKBP11 | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99872874; called by muse, mutect2, varscan2
- GNA15 | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV99505383; called by muse, mutect2, varscan2
- HERC1 | c.12322G>T p.D4108Y | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101496848; called by muse, mutect2, varscan2
- ITGA5 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99516907; called by muse, mutect2, varscan2
- KDM2B | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs782721730, COSV100997642; called by muse, mutect2, varscan2
- KIAA1755 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV99642602; called by muse, mutect2, varscan2
- KMT2E | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99996899; called by muse, mutect2
- LHX8 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV99634295; called by muse, mutect2, varscan2
- MEX3D | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101183542; called by muse, mutect2
- NOB1 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99264065; called by muse, mutect2, varscan2
- NPEPPS | c.2219C>G p.S740C | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100443688, COSV100443943; called by muse, mutect2, varscan2
- NSMAF | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs757821223, COSV99233331, COSV99233370; called by muse, mutect2, varscan2
- OCM2 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs778218099, COSV57535604; called by muse, mutect2, varscan2
- OR1M1 | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs561502650, COSV101447592, COSV70036776; called by muse, mutect2, varscan2
- OR2M5 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 54/555 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100822868; called by muse, mutect2
- PCDH15 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs1371616601, COSV100226626; called by muse, mutect2, varscan2
- PCDH9 | c.3370G>A p.E1124K (on ENST00000377865 / NM_203487.3; = p.E1090K on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV100123063; called by muse, mutect2, varscan2
- PIK3AP1 | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV100226162; called by muse, mutect2, varscan2
- PKD1 | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.029); catalogued as COSV99238934; called by muse, mutect2, varscan2
- RFX2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.195); catalogued as rs765417588, COSV57944490; called by muse, varscan2
- RHBDF1 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 36/371 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs143220179; called by muse, mutect2
- SMCHD1 | c.5207G>C p.R1736T | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.237); catalogued as COSV99862431; called by muse, mutect2, varscan2
- SRRM2 | c.7465G>A p.D2489N | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as COSV99241688; called by muse, mutect2, varscan2
- STIL | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV54550649; called by muse, mutect2
- SZT2 | c.7924C>T p.R2642* (on ENST00000634258 / NM_001365999.1; = p.R2585* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100987615; called by mutect2, varscan2
- TAF4 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs761827702, COSV53334956; called by muse, varscan2
- TAS2R46 | c.770A>C p.N257T | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV101115503; called by muse, mutect2, varscan2
- TOMM40 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.411); catalogued as COSV52986625, COSV99376250; called by muse, mutect2, varscan2
- TRIM13 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs747854705, COSV100078532; called by muse, mutect2, varscan2
- UNC5C | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV101498013; called by muse, mutect2, varscan2
- YARS1 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65114449; called by muse, mutect2, varscan2
- ZAN | c.4906C>T p.R1636W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs545917447, COSV61809066; called by muse, mutect2, varscan2
- B2M | c.221del p.L74Cfs*29 | Frame Shift Del (DEL) | VAF 17/149 reads (11%) | called by mutect2, pindel, varscan2
- BTBD3 | c.684_707del p.L229_E236del | In Frame Del (DEL) | VAF 19/168 reads (11%) | called by mutect2, pindel
- ACOXL | c.861G>A p.L287= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs750504682, COSV101095835; called by muse, mutect2
- FNDC8 | c.441G>A p.Q147= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as COSV50100440; called by muse, mutect2, varscan2
- GOLGA7B | c.153C>G p.L51= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV100086061; called by muse, varscan2
- HARBI1 | c.1038T>C p.T346= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV100454800; called by muse, mutect2, varscan2
- KIAA1755 | c.1056C>T p.F352= | Silent (SNP) | VAF 44/398 reads (11%) | catalogued as COSV99642595; called by muse, varscan2
- LAMC2 | c.2937C>T p.I979= | Silent (SNP) | VAF 39/251 reads (16%) | catalogued as rs1225593619, COSV99917866; called by muse, mutect2, varscan2
- MC2R | c.501C>A p.I167= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100563165; called by muse, mutect2, varscan2
- NCBP2 | c.51G>A p.L17= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100343890; called by muse, mutect2, varscan2
- NLRP1 | c.2667G>C p.L889= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV99335307; called by muse, mutect2
- OR2C3 | c.759C>T p.Y253= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as rs529863004, COSV63574816; called by muse, mutect2
- ORAI1 | c.744G>C p.L248= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100345493; called by muse, varscan2
- PRDM5 | c.1752G>A p.L584= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV53367941; called by muse, mutect2, varscan2
- PRKAA2 | c.711C>G p.L237= | Silent (SNP) | VAF 81/597 reads (14%) | catalogued as COSV100982887, COSV100983053; called by muse, mutect2, varscan2
- PTER | c.978G>A p.L326= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as COSV100126822; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1644G>A p.A548= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs765822767, COSV54763675; called by muse, mutect2
- SEZ6L | c.1299C>T p.C433= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV50669241, COSV99962809; called by muse, mutect2
- SNRNP200 | c.2703C>G p.L901= | Silent (SNP) | VAF 30/278 reads (11%) | catalogued as COSV100108009; called by muse, mutect2, varscan2
- SUPT20HL1 | c.45C>A p.I15= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- TRIM13 | c.24C>G p.L8= | Silent (SNP) | VAF 32/207 reads (15%) | catalogued as COSV100078529; called by muse, mutect2, varscan2
- UGT3A1 | c.25C>T p.L9= | Silent (SNP) | VAF 22/182 reads (12%) | catalogued as COSV99955239; called by muse, mutect2, varscan2
- USO1 | c.2049C>G p.L683= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99363137; called by muse, mutect2, varscan2
- ZC3H11A | c.1380A>T p.A460= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV100142685; called by muse, mutect2, varscan2
- ZFP64 | c.924C>T p.I308= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs143459892; called by muse, mutect2, varscan2
- ACP6 | c.781-73A>C | Intron (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100984243; called by muse, mutect2, varscan2
